Somatic mutation profile of tumor specimen TCGA-22-1016-01A (aliquot TCGA-22-1016-01A-01W-0782-08) from TCGA case TCGA-22-1016, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.9 years (24,078 days).
Specimen TCGA-22-1016-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 611d33d2-ccb0-4d24-a053-9cff7755fc7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-1016-11A (Solid Tissue Normal), aliquot TCGA-22-1016-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3daa05bd-9558-4191-89cc-1d4b74f19698

The open-access MAF lists 344 somatic variants for this specimen: 268 protein-altering or splice-affecting, 67 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 217, Silent 67, Nonsense Mutation 24, Splice Site 10, Frame Shift Del 9, Frame Shift Ins 4, Splice Region 4, RNA 4, Intron 1, 3'UTR 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PANK3 | c.901A>T p.I301F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs77612793; called by mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 10/86 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.3202G>T p.D1068Y (on ENST00000404938 / NM_001163941.2; = p.D623Y on NM_178559.6) | Missense Mutation (SNP) | VAF 113/205 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51716059; called by muse, mutect2, varscan2
- ABLIM3 | c.1571G>T p.R524L | Missense Mutation (SNP) | VAF 16/225 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV58646569; called by muse, mutect2
- ACCS | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 51/374 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs1362031914, COSV55459505; called by muse, mutect2, varscan2
- ACE2 | c.1471G>T p.V491L | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV53026505; called by muse, mutect2, varscan2
- ACSM4 | c.85C>A p.L29I | Missense Mutation (SNP) | VAF 273/799 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV68068704; called by muse, mutect2, varscan2
- ADAMTS3 | c.1726C>G p.R576G | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54397513, COSV99710659; called by muse, mutect2, varscan2
- AFP | c.1465G>A p.E489K | Missense Mutation (SNP) | VAF 78/355 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.282); catalogued as COSV56925125; called by muse, mutect2, varscan2
- ALDH4A1 | c.1567dup p.A523Gfs*8 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | catalogued as rs754334877; called by mutect2, varscan2
- AMPD1 | c.456G>T p.Q152H | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV62417484; called by muse, mutect2, varscan2
- ANK2 | c.1820A>G p.D607G | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV52176963; called by muse, mutect2, varscan2
- ANKRD26 | c.3548A>G p.E1183G | Missense Mutation (SNP) | VAF 13/148 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV65776972; called by muse, mutect2
- ANKRD34B | c.1287G>T p.R429S | Missense Mutation (SNP) | VAF 142/260 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV58614281; called by muse, mutect2, varscan2
- ANKRD40 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV53334331; called by muse, mutect2, varscan2
- APCDD1 | c.419G>A p.G140D | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV62371988; called by muse, mutect2, varscan2
- ATG16L2 | c.1605C>G p.N535K | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV58362471; called by muse, mutect2, varscan2
- ATP13A4 | c.153C>G p.Y51* | Nonsense Mutation (SNP) | VAF 401/918 reads (44%) | catalogued as COSV55072622; called by muse, mutect2, varscan2
- ATP8B2 | c.1858G>T p.E620* (on ENST00000672630; = p.E587* on NM_001367934.1 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 31/96 reads (32%) | catalogued as COSV59247585; called by muse, mutect2, varscan2
- BAIAP3 | c.1804G>T p.D602Y | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs372927860, COSV50104621; called by muse, mutect2, varscan2
- BBS1 | c.723+1G>A p.X241_splice | Splice Site (SNP) | VAF 12/42 reads (29%) | catalogued as COSV59150626; called by muse, varscan2
- BCL7A | c.387G>T p.E129D | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV55850166; called by muse, mutect2, varscan2
- BLM | c.2468C>T p.S823F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV61925882, COSV61927390; called by muse, mutect2, varscan2
- BSDC1 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 90/480 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV61982127; called by mutect2, varscan2
- CACNA1F | c.5099G>A p.R1700K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.99); PolyPhen benign (0.005); catalogued as COSV59905858; called by muse, mutect2
- CAPN6 | c.278A>G p.Q93R | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV60696244; called by muse, mutect2, varscan2
- CD101 | c.1399G>T p.G467C | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56719743; called by muse, mutect2, varscan2
- CDC6 | c.1181G>A p.C394Y | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1415436932, COSV52931070, COSV52931234; called by muse, mutect2, varscan2
- CHD7 | c.6712G>T p.E2238* | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | catalogued as COSV71113053; called by muse, mutect2, varscan2
- CIITA | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 42/339 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as COSV60854647, COSV60859566; called by muse, mutect2, varscan2
- CLDN18 | c.38T>G p.V13G | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV59303940; called by muse, mutect2, varscan2
- CLDN25 | c.11G>A p.S4N | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.152); catalogued as rs768889315, COSV71620462; called by muse, mutect2, varscan2
- CLK2 | c.16A>T p.R6W | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62877841; called by muse, varscan2
- CMYA5 | c.11162C>A p.T3721K | Missense Mutation (SNP) | VAF 60/241 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1295510453, COSV71408047; called by muse, mutect2, varscan2
- CNTNAP5 | c.1100C>A p.P367H | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70499851; called by muse, mutect2
- CREB3L4 | c.919C>G p.L307V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs374742421; called by muse, mutect2, varscan2
- CSMD3 | c.9495A>T p.L3165F (on ENST00000297405 / NM_001363185.1; = p.L2996F on NM_052900.3) | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as COSV52257692; called by mutect2, varscan2
- CTNNA2 | c.990G>T p.R330S | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1262697787, COSV63586644; called by muse, mutect2, varscan2
- CYP2C19 | c.1095C>A p.S365R | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV64908667; called by muse, mutect2, varscan2
- CYP2C19 | c.1096C>A p.L366M | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.315); catalogued as rs1345358265, COSV64908671; called by muse, mutect2, varscan2
- DAAM2 | c.1830G>T p.W610C | Missense Mutation (SNP) | VAF 92/282 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51372059; called by muse, mutect2, varscan2
- DCLK2 | c.1555G>T p.E519* | Nonsense Mutation (SNP) | VAF 67/972 reads (7%) | catalogued as COSV56208722, COSV56209600; called by muse, mutect2
- DDIAS | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV61272789; called by muse, mutect2, varscan2
- DDX23 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 21/296 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV57283543, COSV57285220; called by muse, mutect2
- DEFB136 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 309/742 reads (42%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.378); catalogued as COSV66363992; called by muse, mutect2, varscan2
- DNAH7 | c.4761C>G p.F1587L | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as COSV56770098, COSV56776303; called by muse, mutect2
- DSCAML1 | c.5242G>T p.E1748* (on ENST00000321322; = p.E1688* on NM_020693.4) | Nonsense Mutation (SNP) | VAF 37/328 reads (11%) | catalogued as COSV58397762; called by muse, mutect2, varscan2
- DTX2 | c.1702A>G p.S568G | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV56863466; called by muse, mutect2
- DUSP6 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54379249; called by mutect2, varscan2
- EBF3 | c.1060G>C p.D354H (on ENST00000355311 / NM_001375392.1; = p.D345H on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/512 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV62481570, COSV62482140; called by muse, mutect2
- ENAM | c.2699C>G p.P900R | Missense Mutation (SNP) | VAF 209/298 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1560405648, COSV68536633; called by muse, mutect2, varscan2
- ENPP1 | c.2266G>T p.A756S | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.531); catalogued as COSV62934629; called by muse, mutect2, varscan2
- F5 | c.324G>T p.K108N | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63126247; called by muse, mutect2
- FAM24A | c.241T>A p.C81S | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.833); catalogued as COSV64406080; called by muse, mutect2, varscan2
- FBXO38 | c.1940C>A p.P647Q | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99693588; called by muse, mutect2, varscan2
- FCRL1 | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV63826421; called by muse, mutect2
- FCRL3 | c.703C>A p.L235I | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV63843642; called by muse, mutect2, varscan2
- FKBP10 | c.982C>A p.Q328K | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as rs1555616658, COSV58638148; called by muse, mutect2, varscan2
- FMN2 | c.4690G>T p.D1564Y | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60443070; called by muse, mutect2, varscan2
- FOXI1 | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 11/96 reads (11%) | catalogued as COSV60389407; called by muse, mutect2, varscan2
- GAD1 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100713818; called by mutect2, varscan2
- GAK | c.3190C>T p.Q1064* | Nonsense Mutation (SNP) | VAF 41/98 reads (42%) | catalogued as COSV58507371; called by muse, mutect2, varscan2
- GIMAP7 | c.864G>C p.W288C | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV57960059; called by muse, mutect2, varscan2
- GIMAP8 | c.877T>C p.W293R | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56230777, COSV56232957; called by muse, mutect2, varscan2
- GJA8 | c.375C>A p.D125E | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as COSV53789718; called by muse, varscan2
- GJA8 | c.376C>A p.Q126K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.395); catalogued as COSV53789729; called by muse, varscan2
- GLRB | c.928G>T p.A310S | Missense Mutation (SNP) | VAF 34/528 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs1250261870, COSV52422029; called by muse, mutect2
- GP5 | c.254A>T p.H85L | Missense Mutation (SNP) | VAF 90/350 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV55467588; called by muse, mutect2, varscan2
- GPC5 | c.1040G>T p.R347L | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV65605013, COSV65615616; called by muse, varscan2
- GPR149 | c.987C>A p.H329Q | Missense Mutation (SNP) | VAF 64/120 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV67668794; called by muse, mutect2, varscan2
- GRIA1 | c.2596G>T p.G866* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as COSV53615081; called by muse, mutect2, varscan2
- HBS1L | c.264G>C p.M88I | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.268); catalogued as rs765554240; called by muse, mutect2, varscan2
- HCLS1 | c.1323A>T p.G441= | Splice Region (SNP) | VAF 84/528 reads (16%) | catalogued as COSV57526108; called by muse, mutect2, varscan2
- HEPHL1 | c.1238C>G p.S413C | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1246577650, COSV59894427; called by muse, mutect2, varscan2
- IBSP | c.735A>C p.R245S | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as COSV56896602; called by muse, mutect2, varscan2
- IFI44L | c.1045T>A p.C349S | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV60728685; called by muse, mutect2, varscan2
- INPPL1 | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1006478277, COSV53357512; called by muse, mutect2
- ISM2 | c.1114+1G>C p.X372_splice (on ENST00000342219 / NM_199296.3; = p.X256_splice on NM_182509.4) | Splice Site (SNP) | VAF 6/25 reads (24%) | catalogued as COSV53636158; called by mutect2, varscan2
- KCND2 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as COSV58594024, COSV58604673; called by muse, mutect2, varscan2
- KCNH1 | c.2065C>A p.H689N (on ENST00000271751 / NM_172362.3; = p.H662N on NM_002238.4) | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55093299; called by muse, mutect2
- KCNIP3 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 176/358 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV54671244; called by muse, mutect2, varscan2
- KLHL32 | c.724C>A p.H242N | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV65113589; called by muse, mutect2, varscan2
- KLHL4 | c.591-1G>T p.X197_splice | Splice Site (SNP) | VAF 20/96 reads (21%) | catalogued as COSV64145678; called by muse, mutect2, varscan2
- KLHL9 | c.1220G>T p.R407L | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV62922213; called by muse, mutect2, varscan2
- KNTC1 | c.5128T>C p.F1710L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.953); catalogued as rs1328858161, COSV61082404; called by muse, mutect2
- KRTAP1-3 | c.402C>A p.C134* | Nonsense Mutation (SNP) | VAF 4/31 reads (13%) | catalogued as COSV60336725; called by muse, mutect2, varscan2
- LCE3E | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.764); catalogued as rs748179368, COSV64232054; called by muse, mutect2, varscan2
- LDB1 | c.295G>T p.E99* (on ENST00000425280 / NM_001321612.2; = p.E63* on NM_003893.5) | Nonsense Mutation (SNP) | VAF 64/326 reads (20%) | catalogued as COSV63288869; called by muse, mutect2, varscan2
- LMF1 | c.1328G>A p.C443Y | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV51900247; called by muse, mutect2, varscan2
- LTBP2 | c.1658G>T p.R553L | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV56211488; called by muse, mutect2, varscan2
- LTK | c.2093G>A p.G698D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs771020055, COSV53028700; called by mutect2, varscan2
- MARK1 | c.878T>C p.V293A | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs923160469, COSV65069813; called by muse, mutect2, varscan2
- MARK2 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1225368156, COSV59286509; called by muse, mutect2
- MAS1 | c.70T>A p.S24T | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.078); catalogued as COSV53121834; called by muse, mutect2
- MBD3L1 | c.12T>A p.S4R | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV59776236; called by muse, mutect2, varscan2
- MCM6 | c.1221-1G>T p.X407_splice | Splice Site (SNP) | VAF 9/270 reads (3%) | catalogued as COSV51468165; called by muse, mutect2
- MRAP2 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 96/248 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs969080190, COSV57634604; called by muse, mutect2, varscan2
- MROH2B | c.687C>A p.Y229* | Nonsense Mutation (SNP) | VAF 41/162 reads (25%) | catalogued as rs1201772851, COSV68185301, COSV68187253; called by muse, mutect2, varscan2
- MRPL53 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 33/134 reads (25%) | catalogued as COSV50688587; called by muse, mutect2, varscan2
- MYH9 | c.1779T>G p.N593K | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53390576; called by muse, mutect2, varscan2
- NBEA | c.1623G>T p.M541I | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as COSV59778904; called by muse, mutect2
- NCF2 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV62315403, COSV62316275; called by muse, mutect2
- NKAP | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1368024930, COSV65056659; called by muse, mutect2, varscan2
- NLRP14 | c.2588T>C p.M863T | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as rs369413951, COSV55068540; called by muse, mutect2, varscan2
- NLRP7 | c.1315G>T p.G439W | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100052522, COSV60178449; called by muse, mutect2
- NRROS | c.935A>G p.N312S | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.085); catalogued as COSV60746955; called by muse, mutect2
- NRXN1 | c.1676G>A p.G559D | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58442928; called by muse, varscan2
- NUDT9 | c.330G>T p.W110C | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56197467; called by muse, mutect2
- NUP98 | c.4244A>C p.Q1415P (on ENST00000359171 / NM_001365126.1; = p.Q1398P on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.106); catalogued as COSV61435952; called by muse, mutect2
- OR11H4 | c.889C>G p.P297A | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59559874, COSV59560660; called by muse, mutect2
- OR12D3 | c.677A>G p.K226R | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.973); catalogued as COSV65829328; called by muse, mutect2, varscan2
- OR51B2 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as COSV60916055, COSV60917267; called by muse, mutect2, varscan2
- OR51B2 | c.427G>T p.G143* | Nonsense Mutation (SNP) | VAF 12/95 reads (13%) | catalogued as rs949105971, COSV60917099, COSV60917276; called by muse, mutect2, varscan2
- OR52M1 | c.195G>T p.L65F | Missense Mutation (SNP) | VAF 81/155 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV64172389; called by muse, mutect2, varscan2
- OR56A1 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 299/498 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57363356; called by muse, mutect2
- OR5D14 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as rs774661407, COSV59455667, COSV59456508, COSV59457570; called by muse, mutect2, varscan2
- OR5H6 | c.220C>T p.P74S (on ENST00000642105; = p.P58S on NM_001005479.2) | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV101051831, COSV67351873; called by muse, mutect2, varscan2
- PABPC4 | c.1693dup p.Q565Pfs*37 | Frame Shift Ins (INS) | VAF 15/139 reads (11%) | catalogued as rs769044699; called by mutect2, varscan2
- PCDH15 | c.3012G>A p.L1004= | Splice Region (SNP) | VAF 5/42 reads (12%) | catalogued as COSV57358374; called by mutect2, varscan2
- PCDHA8 | c.2092G>C p.V698L | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.029); catalogued as COSV100968966, COSV65329923; called by muse, mutect2, varscan2
- PCDHB10 | c.1265C>T p.T422I | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.33); catalogued as rs1358381709, COSV53381710; called by muse, mutect2, varscan2
- PCDHGA1 | c.1349del p.P450Qfs*25 | Frame Shift Del (DEL) | VAF 65/129 reads (50%) | catalogued as rs1561472048; called by mutect2, pindel, varscan2
- PCDHGA4 | c.1741C>A p.L581I | Missense Mutation (SNP) | VAF 16/567 reads (3%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.054); catalogued as COSV53995450; called by muse, mutect2
- PKHD1L1 | c.3883C>A p.L1295I | Missense Mutation (SNP) | VAF 302/393 reads (77%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs915964728, COSV65748582; called by muse, mutect2, varscan2
- POLN | c.1811C>A p.T604K | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); catalogued as rs376518009, COSV67026602; called by muse, mutect2, varscan2
- PPARGC1A | c.2110G>C p.E704Q | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); catalogued as COSV53531321; called by muse, mutect2, varscan2
- PPIG | c.290-2A>G p.X97_splice | Splice Site (SNP) | VAF 30/50 reads (60%) | catalogued as COSV53644788; called by muse, mutect2, varscan2
- PPP2R1A | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 66/90 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs945560047, COSV59046753; called by muse, mutect2, varscan2
- PRDM9 | c.854A>T p.E285V | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1232702147, COSV57003650; called by muse, mutect2, varscan2
- PROSER1 | c.644-2A>T p.X215_splice | Splice Site (SNP) | VAF 16/114 reads (14%) | catalogued as rs750288022, COSV61488834; called by muse, mutect2, varscan2
- PTH2R | c.1340G>T p.R447I | Missense Mutation (SNP) | VAF 78/104 reads (75%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.536); catalogued as rs1473970625, COSV55915814, COSV99782676; called by muse, mutect2, varscan2
- PTPRR | c.1867C>A p.L623I | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51740641; called by muse, varscan2
- RANBP10 | c.887A>C p.Q296P | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV58159895; called by muse, mutect2
- RANBP17 | c.1952G>A p.G651D | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as rs1173206098, COSV66654089; called by muse, mutect2, varscan2
- RAPGEF4 | c.2362T>C p.F788L | Missense Mutation (SNP) | VAF 11/338 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV51405088; called by muse, mutect2
- REV3L | c.5654dup p.S1886Kfs*2 | Frame Shift Ins (INS) | VAF 16/105 reads (15%) | catalogued as rs761303551; called by mutect2, varscan2
- RFX6 | c.1225A>T p.M409L | Missense Mutation (SNP) | VAF 80/168 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.243); catalogued as COSV60587447; called by muse, varscan2
- RNF111 | c.881-1G>A p.X294_splice | Splice Site (SNP) | VAF 15/111 reads (14%) | catalogued as COSV62088401; called by muse, mutect2, varscan2
- RNF169 | c.1472C>A p.S491Y | Missense Mutation (SNP) | VAF 57/891 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.459); catalogued as COSV55132296; called by muse, mutect2
- RYR3 | c.3011C>A p.T1004N | Missense Mutation (SNP) | VAF 131/174 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66801932; called by muse, mutect2, varscan2
- SCN5A | c.45G>C p.R15S | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.437); catalogued as COSV60067743; called by muse, mutect2, varscan2
- SEC23IP | c.1640A>T p.Y547F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64832398; called by muse, mutect2, varscan2
- SELP | c.943C>A p.P315T | Missense Mutation (SNP) | VAF 408/756 reads (54%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.69); catalogued as COSV55255511, COSV55255918; called by muse, mutect2, varscan2
- SFSWAP | c.1903G>T p.E635* | Nonsense Mutation (SNP) | VAF 54/331 reads (16%) | catalogued as COSV55521840, COSV99906117; called by muse, mutect2, varscan2
- SH2D1A | c.274C>A p.Q92K | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV63579395, COSV63579519; called by mutect2, varscan2
- SH3GL2 | c.172C>A p.L58I | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as COSV66052896; called by muse, mutect2
- SLC10A7 | c.573C>G p.I191M | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.51); catalogued as COSV53884735; called by muse, mutect2
- SLC22A9 | c.917G>C p.S306T | Missense Mutation (SNP) | VAF 53/283 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs1801518, COSV54168860; called by muse, mutect2, varscan2
- SLC30A8 | c.755C>A p.T252K | Missense Mutation (SNP) | VAF 149/234 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69974044; called by muse, mutect2, varscan2
- SLCO4C1 | c.2090C>A p.T697K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV60513673; called by muse, mutect2, varscan2
- SNRPN | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.353); catalogued as COSV57599064; called by muse, mutect2, varscan2
- SNTA1 | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 22/262 reads (8%) | catalogued as COSV54128840; called by muse, mutect2
- SPATA2 | c.1315G>C p.G439R | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.277); catalogued as COSV56867610; called by muse, mutect2, varscan2
- SPATS2 | c.1187G>C p.S396T | Missense Mutation (SNP) | VAF 102/566 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.051); catalogued as COSV58921458; called by muse, mutect2, varscan2
- SPHKAP | c.4984C>T p.H1662Y (on ENST00000392056 / NM_001142644.2; = p.H1633Y on NM_030623.3) | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs764335137, COSV60871265; called by muse, mutect2, varscan2
- STK32B | c.94G>C p.G32R | Missense Mutation (SNP) | VAF 42/250 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767165585, COSV51501735; called by muse, mutect2, varscan2
- STK32B | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 43/250 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51501741; called by muse, mutect2, varscan2
- STOML3 | c.762C>A p.S254R | Missense Mutation (SNP) | VAF 116/321 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV65511398; called by muse, mutect2, varscan2
- SYDE2 | c.3409G>A p.E1137K | Missense Mutation (SNP) | VAF 55/161 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV58324633; called by muse, mutect2, varscan2
- TAFA1 | c.294G>T p.M98I | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV72039962, COSV72041491; called by muse, mutect2, varscan2
- TBC1D14 | c.270G>T p.Q90H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.319); catalogued as COSV68986698; called by muse, mutect2, varscan2
- TEC | c.1208G>T p.G403V | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67405702; called by muse, mutect2, varscan2
- TESK2 | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 47/249 reads (19%) | catalogued as rs1181730045, COSV59151600; called by muse, mutect2, varscan2
- TGIF2LX | c.509A>G p.E170G | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV52214728; called by muse, mutect2
- TGIF2LX | c.707A>C p.K236T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV52214739; called by muse, mutect2, varscan2
- TMEM132B | c.98C>G p.S33W | Missense Mutation (SNP) | VAF 68/468 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV54758873; called by muse, varscan2
- TMEM260 | c.293G>T p.C98F | Missense Mutation (SNP) | VAF 106/199 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1170968257, COSV55101404; called by muse, mutect2, varscan2
- TMPRSS11E | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 25/257 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1487467600, COSV59520393; called by muse, mutect2, varscan2
- TNN | c.3059G>C p.G1020A | Missense Mutation (SNP) | VAF 324/502 reads (65%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.734); catalogued as COSV53422442, COSV53431472; called by muse, varscan2
- TNNT3 | c.714+1G>T p.X238_splice (on ENST00000397301 / NM_001367846.1; = p.X227_splice on NM_006757.4) | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as rs113617037, COSV53490228; called by mutect2, varscan2
- TNR | c.2923G>A p.A975T | Missense Mutation (SNP) | VAF 415/688 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV54902062; called by muse, mutect2, varscan2
- TNR | c.2809C>T p.R937W | Missense Mutation (SNP) | VAF 44/499 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs150401432, COSV54882302; called by muse, mutect2
- TOX2 | c.1262A>T p.Q421L (on ENST00000358131 / NM_001098798.2; = p.Q397L on NM_032883.3) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV57891590; called by muse, mutect2, varscan2
- TPH2 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as COSV61593266; called by muse, mutect2, varscan2
- TRAPPC9 | c.589T>C p.Y197H | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as COSV66905612; called by muse, mutect2, varscan2
- TRIM33 | c.1364G>C p.G455A | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV61824536; called by muse, mutect2
- TRIM51 | c.637A>G p.N213D | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV55269080; called by muse, mutect2, varscan2
- TRIM58 | c.1057G>A p.G353R | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1438973082, COSV63571526; called by muse, mutect2, varscan2
- TRMT61B | c.806G>C p.G269A | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV60258601; called by muse, mutect2, varscan2
- TRPS1 | c.3493G>C p.D1165H (on ENST00000220888 / NM_001330599.2; = p.D1178H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55253560; called by muse, mutect2, varscan2
- TSHZ3 | c.2690A>T p.N897I | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV53677647; called by muse, mutect2, varscan2
- TTN | c.86738C>T p.P28913L (on ENST00000591111; = p.P21489L on NM_003319.4) | Missense Mutation (SNP) | VAF 29/113 reads (26%) | PolyPhen probably damaging (0.999); catalogued as COSV60219117; called by muse, mutect2, varscan2
- TUBA1A | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 105/441 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.882); catalogued as COSV55498439; called by muse, mutect2, varscan2
- TYRO3 | c.2168G>T p.W723L | Missense Mutation (SNP) | VAF 24/426 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55485335; called by muse, mutect2
- TYRO3 | c.2169G>T p.W723C | Missense Mutation (SNP) | VAF 23/421 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55485357; called by muse, mutect2
- UBR2 | c.4100G>T p.R1367M | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV65751497; called by muse, mutect2, varscan2
- UGGT2 | c.2356G>T p.E786* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV65077280; called by muse, mutect2, varscan2
- UGT2B15 | c.1381G>T p.A461S | Missense Mutation (SNP) | VAF 80/370 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV57735772; called by muse, mutect2, varscan2
- UHRF1BP1L | c.1573C>T p.Q525* | Nonsense Mutation (SNP) | VAF 9/110 reads (8%) | catalogued as COSV54440432; called by muse, mutect2
- USH2A | c.12082G>T p.A4028S | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV56405914; called by muse, mutect2, varscan2
- USH2A | c.9168T>G p.Y3056* | Nonsense Mutation (SNP) | VAF 389/746 reads (52%) | catalogued as CD115981, COSV56405933; called by muse, mutect2, varscan2
- VPS13D | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs751395719, COSV104419648, COSV62532453; called by muse, mutect2, varscan2
- WDR19 | c.1400G>C p.R467P | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV56468026, COSV99975417; called by muse, mutect2, varscan2
- ZEB2 | c.851G>T p.C284F | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57961947; called by muse, mutect2
- ZNF208 | c.89G>C p.R30T | Missense Mutation (SNP) | VAF 157/267 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV68110279; called by muse, mutect2, varscan2
- ZNF227 | c.2153G>T p.C718F | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57313136; called by muse, mutect2, varscan2
- ZNF229 | c.763C>A p.L255I | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV99349948; called by muse, mutect2, varscan2
- ZNF260 | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 98/233 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV72951222, COSV72951268; called by muse, mutect2, varscan2
- ZNF331 | c.1286A>G p.H429R | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53478575; called by muse, mutect2, varscan2
- ZNF436 | c.665A>T p.H222L | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV58359047; called by muse, mutect2, varscan2
- ZNF527 | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62232977; called by muse, mutect2, varscan2
- ZNF528 | c.124A>T p.R42W | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV64620512; called by muse, mutect2, varscan2
- ZNF560 | c.1043A>T p.Y348F | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.287); catalogued as COSV56870078; called by muse, mutect2, varscan2
- ZNF615 | c.1173G>T p.Q391H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV65034427; called by muse, mutect2, varscan2
- ZNF831 | c.4430C>A p.S1477Y | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.539); catalogued as COSV64043173; called by muse, mutect2
- ZNF99 | c.1275C>G p.C425W | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV68056190; called by muse, mutect2, varscan2
- ACTRT2 | c.466G>T p.V156L | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2
- AHNAK2 | c.11638_11653del p.A3880Tfs*22 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- ANAPC4 | c.464T>A p.I155K | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- ANKLE2 | c.1094C>A p.S365Y | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- APOBEC1 | c.376del p.Q126Kfs*14 | Frame Shift Del (DEL) | VAF 68/164 reads (41%) | called by pindel, varscan2
- ATP2B1 | c.33C>G p.Y11* | Nonsense Mutation (SNP) | VAF 11/100 reads (11%) | called by muse, mutect2, varscan2
- BCS1L | c.668G>A p.R223K | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- CCDC191 | c.1394C>A p.P465Q | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CCDC197 | c.423G>T p.Q141H | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- CCDC87 | c.1648T>C p.S550P | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2
- COASY | c.1486-2del p.X496_splice | Splice Site (DEL) | VAF 10/104 reads (10%) | called by mutect2, pindel
- COL9A2 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- DBT | c.175+2T>C p.X59_splice | Splice Site (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2, varscan2
- DNAH7 | c.2197G>T p.A733S | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.114); called by muse, mutect2
- EFHB | c.490del p.V164Lfs*16 | Frame Shift Del (DEL) | VAF 23/138 reads (17%) | called by mutect2, pindel*, varscan2
- EFTUD2 | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 98/694 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ENPP1 | c.2581A>T p.R861W | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ENPP5 | c.280_281del p.D94Yfs*3 | Frame Shift Del (DEL) | VAF 33/103 reads (32%) | called by mutect2, pindel, varscan2
- EPN1 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2
- ERCC6L | c.2825C>G p.P942R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.02); called by mutect2, varscan2
- FBP1 | c.171C>T p.L57= | Splice Region (SNP) | VAF 19/79 reads (24%) | called by muse, mutect2, varscan2
- FRMPD2B | n.955A>T | Splice Region (SNP) | VAF 57/430 reads (13%) | called by muse, mutect2, varscan2
- GPC5 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- GPR156 | c.658T>G p.Y220D | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- GRHL3 | c.803G>A p.G268D (on ENST00000350501 / NM_198174.3; = p.G273D on NM_021180.3) | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HAS3 | c.847A>T p.I283F | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- HEATR9 | c.1379T>A p.L460* | Nonsense Mutation (SNP) | VAF 17/132 reads (13%) | called by muse, mutect2, varscan2
- HIVEP1 | c.5326G>T p.D1776Y | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- IGHV1-2 | c.41C>A p.A14D | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ITGA1 | c.168T>G p.N56K | Missense Mutation (SNP) | VAF 24/331 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- KCNC2 | c.837T>A p.D279E | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- LONP2 | c.2290G>A p.D764N | Missense Mutation (SNP) | VAF 44/413 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MAPK6 | c.1246G>C p.D416H | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MCOLN3 | c.110A>G p.Q37R | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by mutect2, varscan2
- MED13 | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.437); called by muse, mutect2
- MLYCD | c.240G>C p.E80D | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP13 | c.2516A>C p.H839P | Missense Mutation (SNP) | VAF 21/275 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.105); called by muse, mutect2
- NPC1 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); called by muse, varscan2
- OTOGL | c.3269C>G p.T1090S (on ENST00000547103; = p.T1081S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- PCMTD1 | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCXD1 | c.935A>G p.D312G | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.152); called by muse, mutect2
- PPIAL4A | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 230/411 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.244); called by muse, varscan2
- PRUNE2 | c.7196C>A p.S2399Y | Missense Mutation (SNP) | VAF 48/564 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2
- PTK2 | c.2084C>A p.S695Y | Missense Mutation (SNP) | VAF 48/966 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.054); called by muse, mutect2
- PTPRN2 | c.1280_1295del p.K427Sfs*84 | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | called by mutect2, pindel
- RASGRP1 | c.1376C>A p.S459Y | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- RBM39 | c.1433G>T p.C478F (on ENST00000253363 / NM_001323424.2; = p.C472F on NM_004902.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/402 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- SETBP1 | c.2156G>A p.G719E | Missense Mutation (SNP) | VAF 74/143 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPN | c.460del p.A154Qfs*54 | Frame Shift Del (DEL) | VAF 19/106 reads (18%) | called by mutect2, pindel, varscan2
- STK32C | c.571del p.D191Tfs*3 | Frame Shift Del (DEL) | VAF 9/83 reads (11%) | called by mutect2*, varscan2
- STT3B | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- THADA | c.5368C>T p.Q1790* | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.55852G>A p.D18618N (on ENST00000591111; = p.D11194N on NM_003319.4) | Missense Mutation (SNP) | VAF 183/993 reads (18%) | PolyPhen possibly damaging (0.677); called by muse, varscan2
- XKR3 | c.1332C>G p.C444W | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZAN | c.3866G>T p.G1289V | Missense Mutation (SNP) | VAF 32/348 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZMYND15 | c.1988C>T p.T663I (on ENST00000433935 / NM_001136046.3; = p.T624I on NM_032265.2) | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.99); called by muse, mutect2
- ZNF300 | c.1578_1579del p.C526Wfs*27 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by pindel, varscan2
- ZNF454 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- ZNF567 | c.1488C>G p.H496Q (on ENST00000536254 / NM_001322913.1; = p.H465Q on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.034); called by muse, varscan2
- ZNF862 | c.2274_2275insGCCTCTCTCTCCTGCTTAGTCCCTATGTTTCT p.S759Afs*17 | Frame Shift Ins (INS) | VAF 25/52 reads (48%) | called by mutect2, varscan2*
- ZNRF4 | c.1247A>G p.Y416C | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- ZSWIM3 | c.711C>G p.F237L | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- A2ML1 | c.3216C>G p.P1072= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV55295175; called by muse, mutect2
- AADACL2 | c.438G>A p.R146= | Silent (SNP) | VAF 47/485 reads (10%) | called by muse, mutect2
- ACSM2A | c.96C>A p.S32= | Silent (SNP) | VAF 102/133 reads (77%) | catalogued as COSV54581715, COSV54587680; called by muse, mutect2, varscan2
- ACTN2 | c.669G>T p.L223= | Silent (SNP) | VAF 97/163 reads (60%) | catalogued as COSV63977077; called by muse, mutect2, varscan2
- ARAP2 | c.1707A>G p.L569= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs763786030, COSV58289824; called by muse, mutect2, varscan2
- ATP9B | c.2844G>T p.V948= | Silent (SNP) | VAF 22/266 reads (8%) | called by muse, mutect2
- C1orf105 | c.27T>A p.S9= | Silent (SNP) | VAF 42/127 reads (33%) | called by muse, mutect2, varscan2
- C5orf15 | c.300A>T p.A100= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV51548816; called by muse, mutect2, varscan2
- C8A | c.810A>T p.S270= | Silent (SNP) | VAF 59/133 reads (44%) | catalogued as COSV63485672; called by muse, mutect2, varscan2
- CACNA1A | c.5598G>A p.P1866= | Silent (SNP) | VAF 15/169 reads (9%) | catalogued as rs144137960; called by muse, mutect2
- CACNA1D | c.2727C>A p.I909= (on ENST00000350061 / NM_001128840.3; = p.I929= on NM_000720.4) | Silent (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- CD5L | c.570C>T p.R190= | Silent (SNP) | VAF 28/439 reads (6%) | catalogued as COSV63822670; called by muse, mutect2
- CHST8 | c.609C>A p.S203= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV52861307; called by muse, mutect2, varscan2
- CLCA2 | c.2061G>A p.L687= | Silent (SNP) | VAF 14/186 reads (8%) | called by mutect2, varscan2
- DCAF8L1 | c.1656G>T p.V552= | Silent (SNP) | VAF 84/257 reads (33%) | catalogued as COSV71595425; called by muse, mutect2, varscan2
- DLX4 | c.510C>A p.S170= (on ENST00000240306 / NM_138281.3; = p.S98= on NM_001934.3) | Silent (SNP) | VAF 19/630 reads (3%) | called by muse, mutect2
- DNAH5 | c.2868C>T p.R956= | Silent (SNP) | VAF 40/304 reads (13%) | catalogued as rs767246326, COSV54204914; called by muse, mutect2, varscan2
- DOCK2 | c.4563C>A p.T1521= | Silent (SNP) | VAF 34/232 reads (15%) | catalogued as COSV56974876; called by muse, mutect2, varscan2
- DPEP3 | c.622C>T p.L208= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as rs1409295298, COSV52052160; called by muse, mutect2
- EMILIN3 | c.1441C>T p.L481= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs1215911140, COSV60037644; called by muse, mutect2, varscan2
- EVC2 | c.2616G>T p.R872= | Silent (SNP) | VAF 51/118 reads (43%) | catalogued as COSV60398622; called by muse, mutect2, varscan2
- F5 | c.633C>T p.I211= | Silent (SNP) | VAF 15/259 reads (6%) | catalogued as rs778943408, COSV63126947; called by muse, mutect2
- GALNT16 | c.1377C>A p.I459= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV61886988; called by muse, mutect2, varscan2
- GPR27 | c.145C>T p.L49= | Silent (SNP) | VAF 39/53 reads (74%) | called by muse, mutect2, varscan2
- GPR31 | c.99G>T p.A33= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV64761822; called by muse, mutect2, varscan2
- GPX7 | c.453A>T p.P151= | Silent (SNP) | VAF 58/190 reads (31%) | catalogued as COSV63652778; called by muse, mutect2, varscan2
- GRB10 | c.1164G>T p.T388= (on ENST00000398812; = p.T342= on NM_001001549.3) | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV60008206, COSV60009659; called by muse, mutect2, varscan2
- HNRNPK | c.1353G>C p.L451= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as COSV61090407; called by muse, varscan2
- HS3ST4 | c.1200A>T p.P400= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV58824639; called by mutect2, varscan2
- HUWE1 | c.12270C>T p.T4090= | Silent (SNP) | VAF 58/303 reads (19%) | catalogued as COSV53356819; called by muse, mutect2, varscan2
- IGLV3-10 | c.243T>C p.S81= | Silent (SNP) | VAF 70/186 reads (38%) | catalogued as rs769686703; called by muse, mutect2, varscan2
- ISLR2 | c.507G>T p.A169= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as COSV62302898; called by muse, varscan2
- KCND2 | c.375C>A p.I125= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV58578437; called by muse, mutect2, varscan2
- KLHDC10 | c.516G>T p.T172= | Silent (SNP) | VAF 53/203 reads (26%) | catalogued as COSV59050562, COSV59053112; called by muse, mutect2, varscan2
- LILRA2 | c.1248G>T p.V416= | Silent (SNP) | VAF 40/197 reads (20%) | catalogued as COSV52193961; called by muse, mutect2, varscan2
- MAGED2 | c.408A>C p.T136= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV54498793; called by muse, mutect2, varscan2
- MGA | c.6747T>C p.N2249= (on ENST00000219905 / NM_001164273.1; = p.N2040= on NM_001080541.2) | Silent (SNP) | VAF 46/257 reads (18%) | called by muse, mutect2, varscan2
- NCAPG2 | c.3237G>T p.V1079= | Silent (SNP) | VAF 8/164 reads (5%) | catalogued as COSV51989935; called by muse, mutect2
- NSD2 | c.1131A>T p.S377= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV56393892; called by muse, mutect2, varscan2
- OR13C9 | c.735G>T p.L245= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV52243008; called by muse, mutect2, varscan2
- OR14K1 | c.297C>T p.L99= | Silent (SNP) | VAF 60/933 reads (6%) | called by muse, mutect2
- OR5D18 | c.732C>T p.S244= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as rs866560731, COSV100450775, COSV61738059; called by muse, mutect2, varscan2
- OR5J2 | c.774C>T p.S258= | Silent (SNP) | VAF 17/317 reads (5%) | catalogued as COSV56621842, COSV56621992, COSV56622459; called by muse, mutect2
- OTUD5 | c.930C>T p.P310= | Silent (SNP) | VAF 812/890 reads (91%) | called by muse, mutect2, varscan2
- PCDHAC2 | c.2199C>A p.R733= | Silent (SNP) | VAF 9/146 reads (6%) | called by muse, mutect2
- PCDHB8 | c.2082G>T p.A694= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV50804973; called by muse, mutect2, varscan2
- PPP2CB | c.204C>T p.L68= | Silent (SNP) | VAF 32/250 reads (13%) | called by muse, mutect2, varscan2
- PRAMEF14 | c.585C>A p.L195= | Silent (SNP) | VAF 341/607 reads (56%) | called by mutect2, varscan2
- RPTN | c.831A>T p.L277= | Silent (SNP) | VAF 68/630 reads (11%) | catalogued as COSV60168309; called by muse, mutect2, varscan2
- SCN10A | c.219A>G p.E73= | Silent (SNP) | VAF 46/518 reads (9%) | catalogued as COSV71862303; called by muse, mutect2
- SLC25A28 | c.843A>G p.P281= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV65125595; called by muse, mutect2, varscan2
- SLC27A6 | c.69G>C p.L23= | Silent (SNP) | VAF 174/240 reads (73%) | catalogued as COSV52485530; called by muse, varscan2
- SMAD1 | c.1329C>T p.P443= | Silent (SNP) | VAF 142/657 reads (22%) | catalogued as COSV57472564; called by muse, mutect2, varscan2
- SYCP1 | c.189T>C p.D63= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV65699806; called by muse, mutect2, varscan2
- SYNE1 | c.16665A>G p.A5555= (on ENST00000367255 / NM_182961.4; = p.A5484= on NM_033071.3) | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as rs1042078718, COSV55047361; called by muse, mutect2
- TGM6 | c.1543C>T p.L515= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs371303959, COSV52482523; called by muse, mutect2, varscan2
- THBS2 | c.414C>T p.S138= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as rs1405909235, COSV64681000; called by muse, mutect2, varscan2
- TMC5 | c.1404C>T p.F468= (on ENST00000396229 / NM_001105248.1; = p.F222= on NM_024780.5) | Silent (SNP) | VAF 78/206 reads (38%) | catalogued as COSV54906685, COSV54907341; called by muse, mutect2, varscan2
- TRIP13 | c.747G>T p.V249= | Silent (SNP) | VAF 65/869 reads (7%) | called by muse, mutect2
- TRPM1 | c.2982C>A p.P994= | Silent (SNP) | VAF 208/449 reads (46%) | called by muse, mutect2, varscan2
- TRPV5 | c.159C>A p.S53= | Silent (SNP) | VAF 61/516 reads (12%) | catalogued as COSV54686015; called by muse, mutect2, varscan2
- UBE2NL | c.381G>A p.V127= | Silent (SNP) | VAF 18/90 reads (20%) | called by muse, mutect2, varscan2
- USP48 | c.396C>T p.G132= | Silent (SNP) | VAF 25/738 reads (3%) | called by muse, mutect2
- VAMP7 | c.297A>G p.P99= | Silent (SNP) | VAF 47/277 reads (17%) | catalogued as COSV52902443; called by muse, varscan2
- VPS45 | c.303G>C p.V101= | Silent (SNP) | VAF 20/139 reads (14%) | catalogued as COSV64888521; called by muse, mutect2, varscan2
- VWA8 | c.3384C>T p.L1128= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs779325167; called by muse, varscan2
- ZSCAN2 | c.1053G>A p.T351= | Silent (SNP) | VAF 8/226 reads (4%) | catalogued as rs1434448229, COSV57571957; called by muse, mutect2
- C3P1 | n.2321A>T | RNA (SNP) | VAF 31/144 reads (22%) | called by muse, mutect2, varscan2
- EI24P4 | n.1019G>T | RNA (SNP) | VAF 94/522 reads (18%) | catalogued as rs765034927; called by mutect2, varscan2
- EXOC3 | chr5:442670 G>T | 5'Flank (SNP) | VAF 35/688 reads (5%) | called by muse, mutect2
- HMGB1P1 | n.214G>T | RNA (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- JMJD6 | chr17:76716702 C>T | 3'Flank (SNP) | VAF 11/220 reads (5%) | called by muse, mutect2
- LIN9 | c.244+456G>C | Intron (SNP) | VAF 45/96 reads (47%) | catalogued as rs764076330, COSV60246182; called by muse, mutect2, varscan2
- NDUFAF5 | c.-2A>T | 5'UTR (SNP) | VAF 32/74 reads (43%) | catalogued as COSV99176377; called by mutect2, varscan2
- SSPOP | n.7447C>A | RNA (SNP) | VAF 11/33 reads (33%) | catalogued as COSV50488576; called by muse, mutect2, varscan2
- STAT1 | c.*2G>T | 3'UTR (SNP) | VAF 6/81 reads (7%) | called by muse, mutect2
